Somatic mutation profile of tumor specimen TCGA-ER-A19L-06A (aliquot TCGA-ER-A19L-06A-12D-A197-08) from TCGA case TCGA-ER-A19L, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 45.6 years (16,652 days).
Specimen TCGA-ER-A19L-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 393ee2ac-565a-436b-a190-5a3f7d3ed1de.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-ER-A19L-10A (Blood Derived Normal), aliquot TCGA-ER-A19L-10A-01D-A199-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bcbe28f6-f4e2-4265-b5ad-7f09815d79b4

The open-access MAF lists 66 somatic variants for this specimen: 43 protein-altering or splice-affecting, 22 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 38, Silent 22, Nonsense Mutation 2, Splice Site 2, Intron 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.151-1G>A p.X51_splice | Splice Site (SNP) | VAF 26/47 reads (55%) | hotspot (GDC flag); catalogued as CS014428, CS067079, COSV58682903, COSV58695350, COSV58708670, COSV58717973; called by muse, mutect2, varscan2
- ACAP1 | c.1360T>C p.F454L | Missense Mutation (SNP) | VAF 12/84 reads (14%) | SIFT tolerated (0.37); PolyPhen probably damaging (0.992); catalogued as rs143351258; called by muse, mutect2, varscan2
- BAHCC1 | c.1426C>T p.P476S | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT tolerated (0.32); PolyPhen benign (0.413); catalogued as rs1555652959, COSV57030733; called by muse, mutect2, varscan2
- BMP2K | c.1703C>T p.P568L | Missense Mutation (SNP) | VAF 29/38 reads (76%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.028); catalogued as COSV58597525; called by muse, mutect2, varscan2
- CCDC170 | c.2059C>T p.Q687* | Nonsense Mutation (SNP) | VAF 45/100 reads (45%) | catalogued as COSV53343930; called by muse, mutect2, varscan2
- CDH6 | c.1571C>T p.S524L | Missense Mutation (SNP) | VAF 47/62 reads (76%) | SIFT tolerated (0.31); PolyPhen benign (0.066); catalogued as rs202247793, COSV54065357; called by muse, mutect2, varscan2
- CNTN5 | c.2041G>A p.E681K | Missense Mutation (SNP) | VAF 48/64 reads (75%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV54285866; called by muse, mutect2, varscan2
- CTNND2 | c.3173C>T p.S1058F | Missense Mutation (SNP) | VAF 42/88 reads (48%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.974); catalogued as COSV58909397; called by muse, mutect2, varscan2
- ECEL1 | c.2279G>T p.C760F | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58813532; called by muse, mutect2, varscan2
- FOXN2 | c.557T>C p.L186S | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV61319168; called by muse, mutect2, varscan2
- FREM1 | c.1759C>T p.L587F | Missense Mutation (SNP) | VAF 70/96 reads (73%) | SIFT tolerated (0.05); PolyPhen benign (0.191); catalogued as COSV66527194; called by muse, mutect2, varscan2
- GRIA4 | c.1621G>A p.D541N | Missense Mutation (SNP) | VAF 40/51 reads (78%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.696); catalogued as COSV56909972; called by muse, mutect2, varscan2
- GRIN2A | c.1900T>A p.W634R | Missense Mutation (SNP) | VAF 34/73 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58047604; called by muse, mutect2, varscan2
- HIVEP2 | c.2177C>T p.S726F | Missense Mutation (SNP) | VAF 40/78 reads (51%) | SIFT deleterious (0.03); PolyPhen benign (0.072); catalogued as rs754278327, COSV50031237; called by muse, mutect2, varscan2
- HOXA11 | c.923C>T p.S308L | Missense Mutation (SNP) | VAF 31/85 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.392); catalogued as COSV50053983; called by muse, mutect2, varscan2
- IL1R1 | c.658G>A p.E220K | Missense Mutation (SNP) | VAF 45/123 reads (37%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as COSV52107306; called by muse, mutect2, varscan2
- IL9R | c.406G>A p.D136N | Missense Mutation (SNP) | VAF 30/103 reads (29%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.663); catalogued as rs1447368781, COSV54900301; called by muse, mutect2, varscan2
- KCNIP4 | c.568G>A p.D190N | Missense Mutation (SNP) | VAF 23/58 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs752727409, COSV54842738; called by muse, mutect2, varscan2
- LGSN | c.679C>T p.P227S | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT tolerated (0.17); PolyPhen benign (0.034); catalogued as COSV65726718; called by muse, mutect2, varscan2
- MBD3 | c.820G>C p.D274H | Missense Mutation (SNP) | VAF 21/46 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.013); catalogued as COSV50084741; called by muse, mutect2, varscan2
- MEPE | c.1018G>A p.D340N | Missense Mutation (SNP) | VAF 43/51 reads (84%) | SIFT tolerated (0.06); PolyPhen benign (0.216); catalogued as rs776051454, COSV63072078; called by muse, mutect2, varscan2
- MROH9 | c.1019C>T p.P340L | Missense Mutation (SNP) | VAF 19/40 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63012530; called by muse, mutect2, varscan2
- NID2 | c.1994C>T p.P665L | Missense Mutation (SNP) | VAF 71/177 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53500154; called by muse, mutect2, varscan2
- NKTR | c.2361A>C p.K787N | Missense Mutation (SNP) | VAF 43/95 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.245); catalogued as COSV51773868; called by muse, mutect2, varscan2
- NPSR1 | c.147+1G>A p.X49_splice | Splice Site (SNP) | VAF 30/61 reads (49%) | catalogued as COSV62205059; called by muse, mutect2, varscan2
- PAMR1 | c.1769C>T p.S590F (on ENST00000619888 / NM_001001991.3; = p.S607F on NM_015430.4) | Missense Mutation (SNP) | VAF 18/23 reads (78%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.452); catalogued as COSV53514256; called by muse, mutect2, varscan2
- PDZD2 | c.2039C>T p.P680L | Missense Mutation (SNP) | VAF 15/26 reads (58%) | SIFT deleterious (0); PolyPhen benign (0.225); catalogued as COSV56866614, COSV99224378; called by muse, mutect2, varscan2
- PELI2 | c.212T>G p.I71S | Missense Mutation (SNP) | VAF 34/72 reads (47%) | SIFT tolerated (0.09); PolyPhen benign (0.309); catalogued as COSV50713608; called by muse, varscan2
- PKDREJ | c.2143T>A p.S715T | Missense Mutation (SNP) | VAF 23/77 reads (30%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.634); catalogued as COSV53551387; called by muse, mutect2, varscan2
- PLXDC2 | c.641C>T p.S214L | Missense Mutation (SNP) | VAF 43/53 reads (81%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV65906769; called by muse, mutect2, varscan2
- PLXDC2 | c.1007C>T p.P336L | Missense Mutation (SNP) | VAF 42/52 reads (81%) | SIFT tolerated (0.43); PolyPhen benign (0.208); catalogued as COSV65906774; called by muse, varscan2
- PTPRD | c.2716G>A p.E906K | Missense Mutation (SNP) | VAF 24/32 reads (75%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.943); catalogued as COSV61967448; called by muse, mutect2, varscan2
- RARS1 | c.175C>T p.R59* | Nonsense Mutation (SNP) | VAF 22/55 reads (40%) | catalogued as rs749027104, COSV51562587; called by muse, mutect2, varscan2
- SALL4 | c.2986C>T p.P996S | Missense Mutation (SNP) | VAF 29/102 reads (28%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.996); catalogued as rs1468774027, COSV53854635; called by muse, mutect2, varscan2
- TAS2R60 | c.639G>A p.M213I | Missense Mutation (SNP) | VAF 44/122 reads (36%) | SIFT tolerated (0.46); PolyPhen benign (0.018); catalogued as rs141559059, COSV60330146; called by muse, varscan2
- TCF3 | c.222C>T p.T74= | Splice Region (SNP) | VAF 8/26 reads (31%) | catalogued as rs751889696, COSV53651804; called by muse, mutect2
- USH1C | c.658C>G p.R220G | Missense Mutation (SNP) | VAF 10/16 reads (63%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.544); catalogued as COSV50025317; called by muse, varscan2
- ZNF334 | c.1817G>T p.G606V | Missense Mutation (SNP) | VAF 40/268 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV61619535; called by muse, mutect2, varscan2
- ZNF536 | c.1878G>A p.M626I | Missense Mutation (SNP) | VAF 66/181 reads (36%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV62817745; called by muse, mutect2, varscan2
- OPRPN | c.82C>G p.P28A | Missense Mutation (SNP) | VAF 30/43 reads (70%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.909); called by muse, varscan2
- RERE | c.4351C>T p.P1451S | Missense Mutation (SNP) | VAF 3/46 reads (7%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.995); called by muse, mutect2
- SPATA31A3 | c.449C>T p.S150F | Missense Mutation (SNP) | VAF 99/487 reads (20%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.899); called by muse, mutect2, varscan2
- VARS1 | c.1088C>T p.S363F | Missense Mutation (SNP) | VAF 97/291 reads (33%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.761); called by muse, mutect2, varscan2
- ATAD5 | c.4701G>A p.K1567= | Silent (SNP) | VAF 15/45 reads (33%) | catalogued as COSV58977003; called by muse, mutect2, varscan2
- DMRT2 | c.1326G>A p.T442= | Silent (SNP) | VAF 84/99 reads (85%) | catalogued as rs768987240, COSV52402365; called by muse, mutect2, varscan2
- DNMT1 | c.4590C>T p.P1530= | Silent (SNP) | VAF 33/69 reads (48%) | catalogued as rs572638597, COSV61581842; called by muse, mutect2, varscan2
- HMGCS2 | c.1524C>G p.V508= | Silent (SNP) | VAF 624/2376 reads (26%) | catalogued as COSV65568719; called by muse, varscan2
- IZUMO2 | c.612C>T p.V204= | Silent (SNP) | VAF 31/74 reads (42%) | catalogued as COSV53230846; called by muse, mutect2, varscan2
- LLGL2 | c.2256C>T p.A752= | Silent (SNP) | VAF 27/36 reads (75%) | catalogued as rs761815831, COSV51379811; called by muse, mutect2, varscan2
- LRIT2 | c.1560C>T p.S520= | Silent (SNP) | VAF 66/96 reads (69%) | catalogued as COSV60564803; called by muse, mutect2, varscan2
- MYO15A | c.522C>T p.F174= | Silent (SNP) | VAF 26/56 reads (46%) | catalogued as COSV52754263, COSV52754760; called by muse, mutect2, varscan2
- NEIL3 | c.1488C>T p.G496= | Silent (SNP) | VAF 25/33 reads (76%) | catalogued as rs772526444, COSV52812418; called by muse, mutect2, varscan2
- OR9G4 | c.244C>T p.L82= | Silent (SNP) | VAF 57/148 reads (39%) | catalogued as rs747797303, COSV57249159; called by muse, mutect2, varscan2
- OTUD7A | c.195G>A p.Q65= | Silent (SNP) | VAF 42/91 reads (46%) | catalogued as COSV61041423; called by muse, mutect2, varscan2
- PELP1 | c.3150C>T p.P1050= | Silent (SNP) | VAF 16/53 reads (30%) | catalogued as COSV52590537; called by muse, mutect2, varscan2
- PPP1R3A | c.1602C>T p.F534= | Silent (SNP) | VAF 21/44 reads (48%) | catalogued as rs267601240, COSV52876979; called by muse, mutect2, varscan2
- PREX2 | c.1323T>C p.N441= | Silent (SNP) | VAF 13/84 reads (15%) | catalogued as COSV55788518; called by muse, mutect2, varscan2
- SLC35D3 | c.1062C>G p.G354= | Silent (SNP) | VAF 16/33 reads (48%) | catalogued as COSV59378103, COSV59378110; called by muse, mutect2, varscan2
- SPATA31A3 | c.450C>T p.S150= | Silent (SNP) | VAF 101/490 reads (21%) | called by muse, mutect2, varscan2
- STC1 | c.273C>T p.F91= | Silent (SNP) | VAF 15/38 reads (39%) | catalogued as rs1175476044, COSV51689319, COSV99282565; called by muse, mutect2, varscan2
- STOML3 | c.109C>T p.L37= | Silent (SNP) | VAF 12/32 reads (38%) | catalogued as rs1181323378, COSV65511404; called by muse, mutect2, varscan2
- TAS2R60 | c.585C>T p.F195= | Silent (SNP) | VAF 70/174 reads (40%) | catalogued as COSV60331563, COSV60332232; called by muse, varscan2
- TRAPPC11 | c.1848A>T p.P616= | Silent (SNP) | VAF 87/277 reads (31%) | catalogued as COSV58218027; called by muse, mutect2, varscan2
- TSHZ2 | c.1929C>T p.A643= | Silent (SNP) | VAF 68/117 reads (58%) | catalogued as COSV61590206; called by muse, mutect2, varscan2
- VARS1 | c.1089C>T p.S363= | Silent (SNP) | VAF 96/287 reads (33%) | catalogued as COSV65155951; called by muse, mutect2, varscan2
- EEF1D | c.-7-2178G>A | Intron (SNP) | VAF 10/60 reads (17%) | catalogued as COSV57821580; called by muse, mutect2
